Surgical pathology report (de-identified scan), TCGA case TCGA-53-7624, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Miami, specimen TCGA-53-7624-01A (Primary Tumor).

[page 1 of 4]
Pathologic Interpretation:

- A. Intra lobar lymph node #11:
- One lymph node with anthracosis.
- No tumor seen.
- B. Right upper lobe, lobectomy for frozen section:
- Moderately to poorly differentiated adenocarcinoma, 6.2 cm. in greatest dimension.
- The tumor penetrates visceral pleura.
- Margins free of tumor.
- Four lymph nodes, no malignancy seen (0/4).
- AJCC pT2, N0, MX
- See Tumor Summary.
- C. Parabronchial lymph node, biopsy:
- One lymph node, no malignancy seen (0/1).
- D. Paraesophageal lymph node #8:
- One lymph node, no malignancy seen (0/1).
- E. Visceral pleural nodule, biopsy:
- Lung parenchyma with foci of bronchioloalveolar hyperplasia.
- No carcinoma seen.
- F. Right tracheal angle lymph node #10:
- Two lymph nodes, no malignancy seen (0/2).
- G. Right superior lobe segment:
- Lung parenchyma with foci of bronchioloalveolar hyperplasia.
- No carcinoma seen.
- H. Subcarinal lymph node #7:
- Two lymph nodes, no malignancy seen (0/2).
- I. Inferior pulmonary lymph node #9:
- Two lymph nodes, no malignancy seen (0/2).
- J. Right distal paratracheal lymph node #R4:
- Four lymph nodes, no malignancy seen (0/4).

Tumor Summary:

Specimen Type: Lobectomy

Laterality: Right

Tumor Site: Upper lobe

Tumor Size:

Greatest dimension: 6.2 cm.

Additional dimensions: 3 x 2.4 cm.

Histologic Type: Adenocarcinoma, not otherwise characterized

Histologic Grade: Poorly differentiated

Pathologic Staging:

[page 2 of 4]
[REDACTED]

PT2: Tumor with any of the following features of size or extent: greater than 3cm in greatest dimension

pN0: No regional lymph node metastasis

pMX: Cannot be assessed

Margins: Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 2 mm.
Specify margin: Soft tissue (chest wall)

Venous (Large Vessel) Invasion (V): Absent

Arterial (Large Vessel) Invasion: Absent

Lymphatic (Small Vessel) Invasion (L): Absent

Pathologic Staging: pT2, N0, MX

[REDACTED]

As the attending pathologist, I attest that I: (i) Examined the relevant preparation(s) for the specimen(s); and (ii) Rendered the diagnosis(es).

[REDACTED]

Amendments

[REDACTED]

Reason: Diagnosis editing/clarification

[REDACTED]

[REDACTED]

Addendum Diagnosis

This addendum is issued after a second review of the gross specimen and the pulmonary conference to clarify that there are adhesions between the tumor and an attached fragment of membranous soft tissue/parietal pleura? which measures approximately 7.5x2.0x0.4 cm. However, the tumor does not penetrate through to reach into the soft tissue margin (section B6). This case was reviewed with [REDACTED]

[REDACTED]

Intraoperative Consultation

B. Right upper lobe, FS: Bronchial margin, free of tumor.
Tumor: Carcinoma, favor adenocarcinoma.

[REDACTED]

[REDACTED]

[page 3 of 4]
Clinical History:

None Provided

Operation Performed

Right thoracotomy

Pre Operative Diagnosis:

Cancer

Specimen(s) Received:

- A: Intra lobar lymph node #11
- B: Right upper lobe
- C: Parabronchial lymph node
- D: Paraesophageal lymph node #8
- E: Visceral pleural nodule
- F: Right tracheal angle lymph node #10
- G: Right superior lobe segment
- H: Subcarinal lymph node #7
- I: Inferior pulmonary lymph node #9
- J: Right distal paratracheal lymph node #R4

Gross Description:

- A. Received in formalin is an ovoid fragment of tan and yellow tissue with anthracotic pigment, measuring 1.2 x 0.9 x 0.5 cm. The fragment is bisected and submitted in toto in one cassette.
- B. Received fresh for frozen section is a 189 grams, 11.7 x 9.3 x 4.7 cm lobe of lung. The pleural surface is smooth, glistening, grey and purple. Upon sectioning, a well-defined, firm, tan and white mass, measuring 6.2 x 3.0 x 2.4 cm is identified. The mass is grossly in contact with the visceral pleura. It has an area of cystic degeneration, measuring 1.8 x 1.3 x 1.2 cm. The mass is up to 6.0 cm from the parenchymal bronchial and vascular resection margins. Other areas of the lung parenchyma are congested and spongy. Four lymph nodes are identified in the hilum. Representative sections are submitted as follows:
- 1 Bronchial and vascular margins for frozen section
- 2 Representative section of the mass for frozen section
- 3&4 Section of the mass in relation with the pleural surface
- 5&6 Mass in relation with adjacent cystic cavity
- 7 Mass in relation with the pulmonary parenchyma
- 8 Other areas of the lung
- 9 Section of the cystic area
- 10 Perihilar lymph nodes
- C. Received in formalin are two ovoid fragments of grey and tan tissue, measuring 0.2 x 0.2 x 0.1 cm in aggregate. Submitted in toto in one cassette.
- D. Received in formalin is an ovoid fragment of tan and grey tissue, measuring 1.3 x 0.7 x 0.3 cm. The fragment is bisected and submitted in toto in one cassette.
- E. Received in formalin is a long wedge biopsy, measuring 3.9 x 0.7 x 0.7 cm. In the pleural surface, a well defined white nodule, measuring 0.1 x 0.1 x 0.1 cm is identified. This lesion is 1.1 cm from the surgical resection margin. The lesion is submitted in toto with the surrounding lung parenchyma in one cassette.
- F. Received in formalin is an irregular fragment of tan and yellow tissue, measuring 1.6 x 0.7 x 0.6 cm. The lymph nodes are identified. The lymph nodes are bisected and submitted in toto in one cassette. One inked in black.
- G. Received in formalin is a lung wedge biopsy, measuring 4.4 x 1.0 x 0.5 cm. The pleural surface is slightly irregular. Upon sectioning, it is spongy, tan and brown. The tissue is submitted in toto for the second margin in one cassette.
- H. Received in formalin are two ovoid fragments of soft, tan and brown tissue with grey discoloration. The largest measures 2.2 x 1.1 x 0.7 cm. The smallest measures 0.5 x 0.4 x 0.2 cm. The specimen is submitted in toto as follows:
- 1 Largest fragment in toto, bisected
- 2 The smallest fragment

[page 4 of 4]
- I. Received in formalin are two ovoid fragments of soft, tan and yellow tissue with anthracotic pigment. The largest measures 1.3 x 0.7 x 0.3 cm. The smallest measures 0.5 x 0.3 x 0.2 cm. The fragments are bisected and submitted in toto in one cassette (the smallest fragment inked in black)
- J. Received in formalin is an irregular fragment of fibroadipose tissue, measuring 3.5 x 2.7 x 1.0 cm. Four lymph nodes are identified. The lymph nodes are submitted in toto as follows:
- 1 One lymph node bisected
- 2 One lymph node bisected
- 3 Two lymph nodes

Source: NCI Genomic Data Commons file 4f4d1f74-3b82-4e45-b80e-614ad505c8d3 (TCGA-53-7624.B108A209-518B-4271-A90C-7F3857044581.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).